Somatic mutation profile of tumor specimen 0DRQT0 from CCDI case PBCGXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,233 days).
Specimen 0DRQT0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff2c802-f5d0-4405-bac8-bc0efaa19c65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c87aad-300a-4583-b1fa-63a5e9423a4f

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCRLB | c.540del p.M181Cfs*8 | Frame Shift Del (DEL) | VAF 110/540 reads (20%) | catalogued as COSV100396119; called by mutect2, pindel, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 16/574 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CNTN5 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CTNND2 | c.2544A>C p.K848N | Missense Mutation (SNP) | VAF 118/558 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NF2 | c.630_654dup p.V219Sfs*17 | Frame Shift Ins (INS) | VAF 48/251 reads (19%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/146 reads (12%) | called by muse, varscan2
